TCGA case TCGA-26-5132 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: University of Florida. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2c5fa2d4-8e35-42e4-8bca-9fb3371a19c8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 74.5 years (27,196 days); Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 40 days; Days to treatment end: 83 days; Treatment dose: 60 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 40 days; Days to treatment end: 83 days; Number of cycles: 1; Treatment dose: 4,620 mg; Prescribed dose: 110; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 205 days; Days to treatment end: 205 days; Number of cycles: 1; Treatment dose: 150 mg/m2; Prescribed dose: 150; Prescribed dose units: mg/m2; Route of administration: Oral.

Follow-up (2 entries)
- Days to follow up: 286 days; Disease response: Tumor Free.
- Karnofsky performance status: 60; ECOG performance status: 2; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-26-5132-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-26-5132-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 0.
  Slide TCGA-26-5132-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-26-5132-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-26-5132-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: Tumor free; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1, Route of administrations: Route of administration: PO.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior Prostate malignancy as per pathology report.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 286 days; disease-specific survival: no event (censored), 286 days; progression-free interval: no event (censored), 286 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-26-5132-01A-01D-1479-01): tumor purity 0.89, ploidy 1.95, whole-genome doublings 0.
